Somatic mutation profile of tumor specimen MMRF_2147_1_BM_CD138pos (aliquot MMRF_2147_1_BM_CD138pos_T1_KHS5U_L09508) from MMRF case MMRF_2147, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,853 days).
Specimen MMRF_2147_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efcc098b-1b49-4f01-a323-e7302f939b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2147_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2147_2_PB_WBC_C1_KHS5U_L09507; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ea90998-1390-42e0-a06c-c93df0d2ac30

The open-access MAF lists 108 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 35, Silent 16, Intron 6, 5'UTR 3, Nonsense Mutation 3, RNA 2, 3'Flank 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCNN1B | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137852708, CM981791; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BPNT2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.037); catalogued as COSV52908056; called by muse, mutect2
- CACNB1 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as COSV60000176; called by muse, mutect2, varscan2
- CCDC168 | c.15284T>A p.I5095K | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs560224497, COSV59423950; called by muse, mutect2, varscan2
- CDK1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100358783; called by muse, mutect2
- CTCFL | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781289904; called by muse, mutect2, varscan2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- FTHL17 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV63266539, COSV63267412; called by muse, mutect2, varscan2
- IGHV2-70 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs188243654; called by muse, varscan2
- MFAP3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59457256; called by muse, mutect2, varscan2
- MMP15 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs778891660; called by muse, mutect2, varscan2
- NTM | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100868674, COSV66178113; called by muse, mutect2, varscan2
- SALL4 | c.2425G>C p.A809P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.276); catalogued as rs144159154, CD022992; called by muse, mutect2, varscan2
- SCN1B | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs748788661, COSV52896020; called by muse, mutect2, varscan2
- SLC1A3 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as rs369119814, COSV54317412; called by muse, mutect2, varscan2
- SYT13 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as rs368306910; called by muse, mutect2
- ANKRD36C | c.62T>G p.F21C | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CRB1 | c.17T>G p.I6S | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DCDC1 | c.1605T>G p.H535Q | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DHX33 | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- ERRFI1 | c.1102A>G p.N368D | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- EVC | c.716T>G p.I239S | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2
- FAM155A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- FAM174C | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXA2 | c.1073T>A p.L358Q (on ENST00000377115 / NM_153675.3; = p.L364Q on NM_021784.5) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FSCN2 | c.74C>G p.T25R | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FXR2 | c.794T>A p.L265* | Nonsense Mutation (SNP) | VAF 32/197 reads (16%) | called by muse, mutect2, varscan2
- GALNT13 | c.973A>G p.R325G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- GRXCR2 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- IGHV2-70 | c.226_243del p.D76_S81del | In Frame Del (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2
- IL37 | c.263_265+10del p.X88_splice | Splice Site (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- KCNK9 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MC5R | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAPEPLD | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 59/165 reads (36%) | called by muse, mutect2, varscan2
- NAV3 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCLO | c.2276T>G p.M759R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTPN21 | c.1275C>G p.D425E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SELENOF | c.4del p.V2* | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- SHMT1 | c.5C>G p.T2R | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2
- SLC12A8 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TENT5D | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2
- TTLL7 | c.2254A>G p.I752V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2
- TTN | c.61852C>G p.P20618A (on ENST00000591111; = p.P13194A on NM_003319.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCT8L2 | c.1182C>T p.H394= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs775966898, COSV63461999; called by muse, mutect2, varscan2
- CNFN | c.229C>A p.R77= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- COL18A1 | c.1590G>A p.A530= (on ENST00000359759 / NM_130444.3; = p.A295= on NM_030582.4) | Silent (SNP) | VAF 12/195 reads (6%) | catalogued as rs758681240, COSV62699257; called by muse, mutect2
- FADS6 | c.123C>T p.G41= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1396048498; called by muse, mutect2, varscan2
- ICA1L | c.321T>C p.D107= | Silent (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- IL22RA1 | c.822G>A p.P274= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs143248338, COSV54629146; called by muse, mutect2, varscan2
- IPO11 | c.2781T>A p.P927= | Silent (SNP) | VAF 34/271 reads (13%) | called by muse, mutect2, varscan2
- MSH5 | c.822C>T p.F274= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV65209396; called by muse, mutect2
- OCA2 | c.2020C>T p.L674= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as CM129763; called by muse, mutect2, varscan2
- PLCXD3 | c.399A>C p.T133= | Silent (SNP) | VAF 31/237 reads (13%) | called by muse, mutect2, varscan2
- PRKCQ | c.2076G>A p.R692= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs770654897, COSV54120041; called by muse, mutect2, varscan2
- SLC4A5 | c.459C>T p.H153= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs370072549; called by muse, mutect2, varscan2
- SLITRK1 | c.696G>A p.K232= | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- TANC1 | c.2739G>A p.V913= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- VPS26B | c.333C>T p.H111= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs758816058, COSV55545752; called by muse, mutect2, varscan2
- ZW10 | c.1722T>C p.F574= | Silent (SNP) | VAF 20/121 reads (17%) | called by mutect2, varscan2
- BCL7A | chr12:122021479 C>G | 5'Flank (SNP) | VAF 54/90 reads (60%) | catalogued as COSV55848997, COSV55852452; called by muse, mutect2, varscan2
- C6orf136 | c.835-12T>C | Intron (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.*56C>A | 3'UTR (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- CCDC170 | c.*1191C>A | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- CCNI2 | c.*860A>G | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- CFAP97 | c.*1945T>A | 3'UTR (SNP) | VAF 9/18 reads (50%) | catalogued as rs938770492; called by muse, mutect2
- CHST10 | c.*658C>A | 3'UTR (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- CNGA4 | c.-60A>T | 5'UTR (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- CORO7 | c.*535A>G | 3'UTR (SNP) | VAF 53/131 reads (40%) | catalogued as rs201884801; called by muse, mutect2, varscan2
- CYB5B | c.*1009A>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- DBH | c.*446C>A | 3'UTR (SNP) | VAF 25/221 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.6162G>A | RNA (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
- DIP2C | c.*1493G>A | 3'UTR (SNP) | VAF 11/77 reads (14%) | catalogued as rs914833905; called by muse, mutect2, varscan2
- DNER | c.*592G>A | 3'UTR (SNP) | VAF 3/46 reads (7%) | catalogued as rs966470017; called by muse, mutect2
- DSTYK | c.*1411C>T | 3'UTR (SNP) | VAF 34/64 reads (53%) | catalogued as rs1054234863; called by muse, mutect2, varscan2
- EGFL8 | c.*99C>T | 3'UTR (SNP) | VAF 45/236 reads (19%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.*2310A>G | 3'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- EXOC6B | c.1980+174T>G | Intron (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- H2AC6 | c.-39G>C | 5'UTR (SNP) | VAF 36/88 reads (41%) | catalogued as rs543457042, COSV58416735; called by muse, mutect2, varscan2
- HNF4G | chr8:75564374 T>C | 3'Flank (SNP) | VAF 10/63 reads (16%) | catalogued as rs1171097718; called by muse, mutect2, varscan2
- HOXD10 | c.*586G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs905805016; called by muse, mutect2
- HS3ST3B1 | c.*1070G>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- KLF6 | c.676+536A>T | Intron (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- KRT80 | c.*1208G>A | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- LDAH | c.*528A>G | 3'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, varscan2
- LENG8 | c.*465T>C | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- MITF | c.*2692G>A | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- NAP1L3 | c.-161C>T | 5'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- NLGN1 | c.*29dup | 3'UTR (INS) | VAF 83/212 reads (39%) | catalogued as rs768355412; called by mutect2, varscan2
- OR2U1P | n.163_169del | RNA (DEL) | VAF 18/199 reads (9%) | called by mutect2, pindel
- PACSIN1 | c.*468C>T | 3'UTR (SNP) | VAF 96/199 reads (48%) | called by muse, mutect2, varscan2
- PCYOX1L | c.*638dup | 3'UTR (INS) | VAF 39/98 reads (40%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.*1100_*1102del | 3'UTR (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- PPP2R2B | c.*103C>T | 3'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as rs893199098; called by muse, mutect2
- RNASEH1 | c.*78C>T | 3'UTR (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- SALL4 | c.*85T>C | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- SCNM1 | c.*13A>G | 3'UTR (SNP) | VAF 10/200 reads (5%) | catalogued as rs1277728104; called by muse, mutect2
- SLC5A3 | c.*6999T>C | 3'UTR (SNP) | VAF 8/69 reads (12%) | catalogued as rs1045061739; called by muse, mutect2, varscan2
- SORCS2 | c.*451C>T | 3'UTR (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- SYDE2 | c.*1003dup | 3'UTR (INS) | VAF 14/98 reads (14%) | catalogued as rs1000539439; called by mutect2, varscan2
- SYNE3 | c.790-210A>T | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- SYT17 | c.183-13T>G | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2
- TAF4 | c.*615C>T | 3'UTR (SNP) | VAF 28/63 reads (44%) | catalogued as rs543197419; called by muse, mutect2, varscan2
- TENM2 | chr5:168263373 C>T | 3'Flank (SNP) | VAF 20/90 reads (22%) | catalogued as rs141488770; called by muse, mutect2, varscan2
- TLL1 | c.*2880A>C | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- UCHL3 | c.475-4956C>T | Intron (SNP) | VAF 38/76 reads (50%) | catalogued as rs1250086721; called by muse, mutect2, varscan2
- UNC80 | c.*818G>A | 3'UTR (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- XPO4 | c.*928T>A | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- ZNF716 | c.*3272T>C | 3'UTR (SNP) | VAF 5/59 reads (8%) | catalogued as rs1335611164; called by muse, mutect2
